Somatic mutation profile of tumor specimen TCGA-VN-A88K-01A (aliquot TCGA-VN-A88K-01A-11D-A34U-08) from TCGA case TCGA-VN-A88K, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.9 years (21,524 days).
Specimen TCGA-VN-A88K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fa3cdea-1a7b-4017-acf9-2f6b52adf6b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VN-A88K-10A (Blood Derived Normal), aliquot TCGA-VN-A88K-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dc4f404-1cf2-4d9c-9dc8-a9c66e7dc552

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRIP1 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 39/120 reads (33%) | catalogued as rs780020495, COSV99370649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKIB1 | c.2938A>G p.M980V | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs745909984, COSV99729600; called by muse, mutect2, varscan2
- ARFGEF1 | c.3607A>G p.N1203D | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.196); catalogued as COSV99143591; called by muse, mutect2, varscan2
- ATM | c.7358G>C p.R2453P | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT tolerated (0.11); PolyPhen benign (0.294); catalogued as rs587781361, COSV53751307, COSV53760488; called by muse, mutect2, varscan2
- CACNA1A | c.4612A>G p.I1538V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as COSV100802951; called by muse, mutect2, varscan2
- GRM1 | c.2941C>T p.R981C | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV51113753; called by muse, mutect2, varscan2
- ING1 | c.406G>T p.G136W | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58170423; called by muse, mutect2, varscan2
- INPP5E | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs753742613, COSV100867263; called by muse, varscan2
- KCNN1 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748526364, COSV55836795, COSV55837632; called by muse, mutect2, varscan2
- NMNAT1 | c.28G>C p.V10L | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as COSV101020433; called by muse, mutect2, varscan2
- OR52A1 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV100200539; called by muse, mutect2, varscan2
- PDILT | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs767360839, COSV56701999; called by muse, mutect2, varscan2
- PHF21B | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as rs995168358, COSV57560048; called by muse, mutect2, varscan2
- PHKB | c.2294A>G p.H765R | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54524091; called by muse, mutect2, varscan2
- RNF113A | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 119/147 reads (81%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV101007061, COSV65097131; called by muse, mutect2, varscan2
- SH2D3C | c.1614G>A p.W538* (on ENST00000314830 / NM_170600.3; = p.W381* on NM_005489.4) | Nonsense Mutation (SNP) | VAF 72/208 reads (35%) | catalogued as COSV100137228; called by muse, mutect2, varscan2
- SLC25A12 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55536617; called by muse, mutect2, varscan2
- STAB2 | c.1484A>G p.N495S | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs527425197, COSV101186164; called by muse, mutect2, varscan2
- UBQLN3 | c.1722T>G p.N574K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100293862; called by muse, mutect2, varscan2
- CLEC6A | c.330G>T p.M110I | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- PRAMEF17 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FBXO24 | c.669T>C p.C223= (on ENST00000241071 / NM_033506.3; = p.C261= on NM_012172.5) | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV99575521; called by muse, mutect2, varscan2
- IRGQ | c.1437C>T p.A479= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs765295100, COSV100338225; called by muse, varscan2
- MBTPS1 | c.1005T>A p.A335= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV100597701; called by muse, mutect2, varscan2
- NRBF2 | c.672G>A p.T224= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs549755878; called by muse, mutect2, varscan2
- ZNF131 | c.1719C>T p.N573= (on ENST00000509156 / NM_001330707.2; = p.N539= on NM_003432.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs1419039253, COSV100185631; called by muse, mutect2, varscan2
